Somatic mutation profile of tumor specimen TCGA-FG-6692-01A (aliquot TCGA-FG-6692-01A-11D-1893-08) from TCGA case TCGA-FG-6692, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 64.0 years (23,374 days).
Specimen TCGA-FG-6692-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63a32894-a889-4ff9-8bfc-426b15c0175e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FG-6692-10A (Blood Derived Normal), aliquot TCGA-FG-6692-10A-01D-1893-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/843811de-847c-4218-8e9e-e6a8d188a05a

The open-access MAF lists 85 somatic variants for this specimen: 57 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 26, Intron 2, Splice Site 2, Frame Shift Del 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 2274/2388 reads (95%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs149840192, COSV51765841, COSV51768139; ClinVar: likely pathogenic; called by muse, varscan2
- PTEN | c.79T>G p.Y27D | Missense Mutation (SNP) | VAF 44/72 reads (61%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as CM147224, COSV64290549, COSV64290556, COSV64292877; called by muse, mutect2, varscan2
- A2M | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as rs759105548, COSV59384321; called by muse, mutect2, varscan2
- ARHGEF28 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.048); catalogued as rs1476513959, COSV55250994; called by muse, mutect2, varscan2
- BTN2A1 | c.503G>A p.R168K | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.08); catalogued as COSV57002624, COSV57003330; called by muse, mutect2, varscan2
- CANT1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56605198; called by muse, mutect2, varscan2
- CHRDL1 | c.283+2T>A p.X95_splice (on ENST00000372045; = p.X101_splice on NM_145234.4) | Splice Site (SNP) | VAF 92/112 reads (82%) | catalogued as CS121192, COSV54323783; called by muse, mutect2, varscan2
- CLUH | c.2039T>C p.L680P (on ENST00000435359; = p.L718P on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV70928222; called by muse, mutect2, varscan2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- COL22A1 | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs761525542, COSV57329385, COSV57364269; called by muse, mutect2
- COL6A3 | c.281A>G p.N94S | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.111); catalogued as COSV55083961; called by muse, mutect2, varscan2
- CRYGB | c.379G>A p.V127M | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs767897845, COSV53679934; called by muse, mutect2, varscan2
- DDX56 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1228134063, COSV51835774, COSV51836305; called by muse, mutect2, varscan2
- DEAF1 | c.666C>T p.G222= | Splice Region (SNP) | VAF 9/60 reads (15%) | catalogued as rs765924884, COSV58606372; called by muse, mutect2, varscan2
- DGKD | c.2218C>T p.R740C (on ENST00000264057 / NM_152879.3; = p.R696C on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.676); catalogued as rs753361193, COSV51036807; called by muse, mutect2, varscan2
- DNAH7 | c.8570A>T p.Q2857L | Missense Mutation (SNP) | VAF 150/386 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56756980; called by muse, mutect2, varscan2
- DOCK4 | c.223T>C p.F75L | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV70316944; called by muse, mutect2, varscan2
- DUSP5 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63645493; called by muse, mutect2, varscan2
- E4F1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs144383218; called by muse, mutect2, varscan2
- FLG2 | c.2050C>T p.H684Y | Missense Mutation (SNP) | VAF 211/548 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV66167375; called by muse, mutect2, varscan2
- FSCB | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV61217313; called by muse, mutect2, varscan2
- GIMAP4 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.862); catalogued as rs778030006, COSV55431588; called by muse, mutect2, varscan2
- GJA3 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV53834595; called by muse, mutect2, varscan2
- IGHD | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs754015544, COSV101162842; called by muse, mutect2, varscan2
- IL31RA | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs142659639; called by muse, mutect2, varscan2
- IRX1 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs774592941, COSV57358580; called by muse, mutect2, varscan2
- ITGAD | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.222); catalogued as rs761780183, COSV101210590, COSV66757244; called by muse, mutect2, varscan2
- KCNA4 | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs747595084, COSV60251264; called by muse, mutect2, varscan2
- KCNJ2 | c.511A>G p.I171V | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.243); catalogued as rs150326473; called by muse, mutect2, varscan2
- KEL | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs747437444, COSV62333999; called by muse, mutect2, varscan2
- LMTK3 | c.3506G>A p.R1169K | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.012); catalogued as COSV54310808; called by muse, mutect2
- LRFN5 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); catalogued as rs762294951, COSV53248846; called by muse, mutect2, varscan2
- MECOM | c.443G>A p.R148Q (on ENST00000468789 / NM_001105078.4; = p.R336Q on NM_004991.4) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1223083082, COSV52959716, COSV99244514; called by muse, mutect2, varscan2
- MPO | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1317237427, COSV56562367; called by muse, mutect2, varscan2
- NAGLU | c.1921A>G p.N641D | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56794410; called by muse, mutect2, varscan2
- NDN | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.068); catalogued as COSV59358224; called by muse, mutect2, varscan2
- NPLOC4 | c.1784C>T p.P595L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.051); catalogued as COSV58615485; called by muse, mutect2, varscan2
- PIMREG | c.245T>C p.L82P | Missense Mutation (SNP) | VAF 47/93 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51470461; called by muse, mutect2, varscan2
- PSKH2 | c.149G>A p.R50H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1357010057, COSV52609793; called by muse, mutect2, varscan2
- RASGRF2 | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.089); catalogued as COSV54122528; called by muse, mutect2, varscan2
- RNASEL | c.2063C>T p.P688L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1236737170, COSV62376430, COSV62377611; called by muse, mutect2, varscan2
- RNF112 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV101518357, COSV71978774; called by muse, mutect2, varscan2
- RP1 | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV55112942; called by muse, mutect2, varscan2
- SDC1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs755438507, COSV54339359; called by muse, mutect2, varscan2
- SERPINB7 | c.79A>T p.N27Y | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60533094; called by muse, mutect2, varscan2
- SHANK1 | c.2620C>T p.R874C | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1188839671, COSV53246173; called by muse, varscan2
- SIVA1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs762902272, COSV57331398; called by muse, mutect2, varscan2
- SMAD1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.117); catalogued as rs370506404; called by muse, mutect2, varscan2
- UBE2D4 | c.367A>G p.I123V | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); catalogued as rs774721530, COSV55972938; called by muse, mutect2, varscan2
- VRK1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53708471; called by muse, varscan2
- WNT11 | c.1031G>T p.C344F | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59443220, COSV59443348; called by muse, mutect2, varscan2
- ZNF331 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 192/692 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV53475721; called by muse, mutect2, varscan2
- ZNF431 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as rs369263368, COSV60672202; called by muse, mutect2, varscan2
- ZNF441 | c.247G>T p.G83* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV63539367; called by muse, mutect2, varscan2
- ZNF98 | c.800A>T p.K267I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as rs879473941; called by muse, mutect2, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 15/26 reads (58%) | called by mutect2, pindel, varscan2
- SPG11 | c.2068-3_2079del p.X690_splice | Splice Site (DEL) | VAF 20/70 reads (29%) | called by mutect2, pindel
- ACER1 | c.285C>T p.L95= | Silent (SNP) | VAF 42/149 reads (28%) | catalogued as COSV56835018; called by muse, mutect2, varscan2
- ADGRL4 | c.900A>T p.V300= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as COSV66060398; called by muse, mutect2, varscan2
- BLK | c.900C>T p.Y300= | Silent (SNP) | VAF 31/76 reads (41%) | catalogued as rs139994406; called by muse, mutect2, varscan2
- DPY19L1 | c.1698A>T p.A566= | Silent (SNP) | VAF 40/141 reads (28%) | catalogued as rs755010584, COSV60581474; called by muse, mutect2, varscan2
- EP400 | c.1563G>T p.P521= | Silent (SNP) | VAF 104/298 reads (35%) | catalogued as rs368365311, COSV57767224; called by muse, mutect2, varscan2
- GMDS | c.486G>A p.V162= | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as COSV66431022; called by muse, mutect2, varscan2
- GREM2 | c.432C>T p.F144= | Silent (SNP) | VAF 45/117 reads (38%) | catalogued as COSV58947874, COSV58951463; called by muse, mutect2, varscan2
- IL4I1 | c.1554G>A p.E518= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs1052260150, COSV55577763; called by muse, mutect2, varscan2
- JPH3 | c.540C>T p.D180= | Silent (SNP) | VAF 42/97 reads (43%) | catalogued as rs758856596, COSV52465625; called by muse, mutect2, varscan2
- KCNK10 | c.1089C>T p.H363= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs201640910, COSV56641254; called by muse, mutect2, varscan2
- LETM1 | c.1398G>A p.L466= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV57099577; called by muse, mutect2, varscan2
- LRRTM4 | c.846G>A p.L282= | Silent (SNP) | VAF 15/28 reads (54%) | catalogued as COSV69139392, COSV69140820; called by muse, mutect2, varscan2
- LTBP2 | c.5046C>T p.P1682= | Silent (SNP) | VAF 62/159 reads (39%) | catalogued as rs1194291909, COSV56206218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH2B | c.639C>T p.H213= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs779094899, COSV68182329; called by muse, mutect2, varscan2
- MYH8 | c.4995G>A p.R1665= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as COSV67961821; called by muse, mutect2, varscan2
- OR1M1 | c.528C>T p.H176= | Silent (SNP) | VAF 67/254 reads (26%) | catalogued as COSV70036345, COSV70036612; called by muse, mutect2, varscan2
- OR4X1 | c.630C>T p.F210= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs200969185, COSV100186735, COSV60722430; called by muse, mutect2, varscan2
- OR4X2 | c.57C>T p.C19= | Silent (SNP) | VAF 62/153 reads (41%) | catalogued as rs1421592968, COSV56582766; called by muse, mutect2, varscan2
- PCDHGA6 | c.2043C>T p.S681= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as rs770848918, COSV53918024; called by muse, mutect2, varscan2
- PRPF39 | c.1794G>A p.L598= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV53531577; called by muse, mutect2, varscan2
- TSPOAP1 | c.717G>A p.R239= | Silent (SNP) | VAF 27/55 reads (49%) | catalogued as COSV52105913; called by muse, mutect2, varscan2
- TTN | c.38046G>A p.K12682= (on ENST00000591111; = p.K5258= on NM_003319.4) | Silent (SNP) | VAF 76/187 reads (41%) | catalogued as rs1424477185, COSV59951508; called by muse, mutect2, varscan2
- VCAM1 | c.1707A>G p.T569= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as COSV54118398; called by muse, mutect2, varscan2
- VEPH1 | c.2490C>T p.T830= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as COSV100747274, COSV62877270; called by muse, mutect2, varscan2
- WDR7 | c.2502G>A p.S834= | Silent (SNP) | VAF 89/232 reads (38%) | catalogued as rs765205475, COSV54350205; called by muse, mutect2, varscan2
- ZNF536 | c.3615C>T p.G1205= | Silent (SNP) | VAF 35/117 reads (30%) | catalogued as rs765448632, COSV62821086; called by muse, mutect2, varscan2
- UGT1A6 | c.862-23302C>T | Intron (SNP) | VAF 120/335 reads (36%) | catalogued as COSV59384832; called by muse, mutect2, varscan2
- USH1C | c.1284+7694C>T | Intron (SNP) | VAF 19/46 reads (41%) | catalogued as COSV50015042, COSV99141700; called by muse, mutect2, varscan2
